Somatic mutation profile of tumor specimen MBCProject_1258_T1_WES (aliquot MBCProject_1258_T1_WES_1) from CMI case MBCProject_1258, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 37.0 years (13,528 days).
Specimen MBCProject_1258_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cce815ee-d41f-4fdd-9260-9804c8700d98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1258_SALIVA (Saliva), aliquot MBCProject_1258_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff3cf17c-91c4-4cb9-9174-55e5977d233d

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Intron 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLU | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 28/453 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs138211435; called by muse, mutect2
- EPAS1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1267580705, COSV55387229; called by muse, mutect2, varscan2
- FAM135B | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs775631073, COSV50522291, COSV50522328; called by mutect2, varscan2
- FBXL8 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs776030467; called by muse, mutect2, varscan2
- FOXD4 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV58698337; called by muse, mutect2
- H2BC21 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 92/348 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as COSV100479607, COSV58611455; called by muse, mutect2, varscan2
- NUAK1 | c.1822C>T p.L608F | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99777352; called by muse, mutect2, varscan2
- PCDH10 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs148933278, COSV52090488; called by muse, mutect2, varscan2
- PCDHGA2 | c.604C>A p.R202S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs377473177, COSV53977480; called by muse, mutect2, varscan2
- PHF12 | c.1743G>T p.W581C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1205656577; called by muse, mutect2, varscan2
- ADGRL3 | c.1052G>C p.G351A (on ENST00000506720 / NM_001322402.2; = p.G283A on NM_015236.6) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKIB1 | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- BRWD3 | c.2531G>A p.W844* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | called by muse, varscan2
- CARNS1 | c.1451T>C p.L484P | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- COL4A4 | c.2983C>A p.P995T | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- GNPTAB | c.3685G>A p.A1229T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- INPPL1 | c.2600G>C p.R867T | Missense Mutation (SNP) | VAF 167/256 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- JAK1 | c.2415del p.Y806Mfs*8 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | called by mutect2, pindel, varscan2
- PZP | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CARNS1 | c.1701T>C p.D567= | Silent (SNP) | VAF 84/147 reads (57%) | catalogued as rs781374752; called by muse, mutect2, varscan2
- CTSW | c.648G>A p.P216= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs143198836; called by muse, mutect2, varscan2
- PEX5L | c.738C>T p.T246= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs771928294, COSV99828289; called by muse, mutect2, varscan2
- RIMBP3 | c.1125G>A p.K375= | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- RASGRP2 | c.-71-341C>T | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- TGM5 | c.11-14C>A | Intron (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
